Somatic mutation profile of tumor specimen HCM-CSHL-0255-C18-01A (aliquot HCM-CSHL-0255-C18-01A-11D-A881-36) from HCMI case HCM-CSHL-0255-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; Tumor grade: G4.
Specimen HCM-CSHL-0255-C18-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 68c4be6b-255e-4eca-8318-836240d61741.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0255-C18-10A (Blood Derived Normal), aliquot HCM-CSHL-0255-C18-10A-01D-A881-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bd6a299c-0c53-4966-8a8a-696454db8c3b

The open-access MAF lists 70 somatic variants for this specimen: 51 protein-altering or splice-affecting, 19 silent.
By variant classification: Missense Mutation 42, Silent 19, Nonsense Mutation 5, Frame Shift Ins 2, In Frame Del 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.637C>T p.R213* | Nonsense Mutation (SNP) | VAF 67/175 reads (38%) | hotspot (GDC flag); catalogued as rs587781392, CM920027, COSV57321978; ClinVar: pathogenic; called by muse, mutect2, varscan2
- BRAF | c.1526G>C p.G509A (on ENST00000288602 / NM_001374244.1; = p.G469A on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 63/326 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.933); catalogued as rs121913355, CM060876, COSV56061424, COSV56062352, COSV56065622; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.586C>T p.R196* | Nonsense Mutation (SNP) | VAF 153/383 reads (40%) | hotspot (GDC flag); catalogued as rs397516435, CM941329, COSV52663748, COSV53125285, COSV53128268; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ADARB2 | c.1255G>A p.E419K | Missense Mutation (SNP) | VAF 92/556 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs374032478; called by muse, mutect2, varscan2
- ADGRD2 | c.2896C>T p.R966W | Missense Mutation (SNP) | VAF 106/531 reads (20%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.007); catalogued as rs1342702827; called by muse, varscan2
- ANKRD6 | c.37C>T p.R13C | Missense Mutation (SNP) | VAF 62/326 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs373880741; called by muse, mutect2, varscan2
- APOB | c.7600C>T p.R2534* | Nonsense Mutation (SNP) | VAF 87/535 reads (16%) | catalogued as rs145143533, CM051005; ClinVar: benign; called by muse, mutect2, varscan2
- CASR | c.1163C>T p.S388L | Missense Mutation (SNP) | VAF 182/626 reads (29%) | SIFT tolerated (0.28); PolyPhen benign (0.012); catalogued as rs377282860, COSV56140790; called by muse, mutect2, varscan2
- COL18A1 | c.2827G>A p.E943K (on ENST00000359759 / NM_130444.3; = p.E708K on NM_030582.4) | Missense Mutation (SNP) | VAF 78/481 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.009); catalogued as rs1271658589; called by muse, mutect2, varscan2
- CYP2D7 | c.269C>T p.A90V | Missense Mutation (SNP) | VAF 158/711 reads (22%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.529); catalogued as rs746357842; called by muse, mutect2, varscan2
- DNM1 | c.1400G>A p.R467H | Missense Mutation (SNP) | VAF 102/440 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.945); catalogued as rs1372243765, COSV57848970; called by muse, mutect2, varscan2
- FAM98A | c.1199G>A p.R400Q | Missense Mutation (SNP) | VAF 87/541 reads (16%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0); catalogued as rs764994064, COSV53210400; called by muse, mutect2, varscan2
- FANCG | c.1621G>A p.V541M | Missense Mutation (SNP) | VAF 85/365 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.621); catalogued as COSV62721400; called by muse, mutect2, varscan2
- FAT3 | c.2372G>A p.R791Q | Missense Mutation (SNP) | VAF 60/343 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs199786266; called by muse, mutect2, varscan2
- G6PC | c.1036G>A p.A346T | Missense Mutation (SNP) | VAF 63/278 reads (23%) | SIFT tolerated (0.22); PolyPhen benign (0.015); catalogued as rs1444458077; called by muse, mutect2, varscan2
- GPNMB | c.1651G>A p.V551M (on ENST00000381990 / NM_001005340.2; = p.V539M on NM_002510.3) | Missense Mutation (SNP) | VAF 71/402 reads (18%) | SIFT tolerated (0.33); PolyPhen benign (0.014); catalogued as rs763870261, COSV51697415; called by muse, mutect2, varscan2
- HYOU1 | c.194G>A p.R65Q | Missense Mutation (SNP) | VAF 51/290 reads (18%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.742); catalogued as rs373116532; called by muse, mutect2, varscan2
- IFITM5 | c.58G>A p.A20T | Missense Mutation (SNP) | VAF 190/713 reads (27%) | SIFT tolerated (0.22); PolyPhen benign (0.019); catalogued as rs747878124, COSV101164327; called by muse, mutect2, varscan2
- KNL1 | c.2680G>A p.D894N (on ENST00000346991 / NM_170589.5; = p.D868N on NM_144508.5) | Missense Mutation (SNP) | VAF 42/185 reads (23%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs765489557, COSV61161312; called by muse, mutect2, varscan2
- LMO7 | c.4083G>T p.E1361D (on ENST00000357063; = p.E1042D on NM_005358.5) | Missense Mutation (SNP) | VAF 91/535 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.637); catalogued as COSV100413536; called by muse, mutect2, varscan2
- NAALADL1 | c.1171C>T p.R391C | Missense Mutation (SNP) | VAF 94/518 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs751516383; called by muse, mutect2, varscan2
- PCDH8 | c.1081G>A p.A361T | Missense Mutation (SNP) | VAF 170/1093 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0.019); catalogued as rs201490995; called by muse, varscan2
- POU3F3 | c.1220G>A p.R407H | Missense Mutation (SNP) | VAF 113/691 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63722060; called by muse, mutect2, varscan2
- RAMP3 | c.427C>T p.R143C | Missense Mutation (SNP) | VAF 81/461 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs370868982; called by muse, mutect2, varscan2
- RPS6KA4 | c.1663G>A p.A555T | Missense Mutation (SNP) | VAF 23/877 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1410769083; called by muse, mutect2
- SARS1 | c.1168C>T p.R390C | Missense Mutation (SNP) | VAF 83/376 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs750961565, COSV52320927; called by muse, mutect2, varscan2
- SEMA6C | c.353C>T p.T118M | Missense Mutation (SNP) | VAF 90/502 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.938); catalogued as rs779953197; called by muse, mutect2, varscan2
- SH3TC1 | c.97C>T p.R33W | Missense Mutation (SNP) | VAF 145/767 reads (19%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as rs761407664; called by muse, mutect2, varscan2
- SKP2 | c.332G>A p.C111Y | Missense Mutation (SNP) | VAF 91/463 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs755887705; called by muse, mutect2, varscan2
- SNX29 | c.1730C>T p.P577L | Missense Mutation (SNP) | VAF 59/480 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as rs752367820; called by muse, mutect2, varscan2
- TRIM44 | c.566A>G p.Y189C | Missense Mutation (SNP) | VAF 109/528 reads (21%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.933); catalogued as rs771838525; called by muse, varscan2
- TRIM67 | c.1171G>A p.V391I | Missense Mutation (SNP) | VAF 68/312 reads (22%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.781); catalogued as rs759061291, COSV64157994; called by muse, mutect2, varscan2
- VNN1 | c.469C>T p.R157C | Missense Mutation (SNP) | VAF 93/385 reads (24%) | SIFT tolerated (0.05); PolyPhen benign (0.12); catalogued as rs774199628, COSV104425749; called by muse, mutect2, varscan2
- ARHGDIB | c.405A>T p.K135N | Missense Mutation (SNP) | VAF 77/347 reads (22%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.555); called by muse, mutect2, varscan2
- ENGASE | c.20C>T p.T7M | Missense Mutation (SNP) | VAF 82/462 reads (18%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); called by muse, mutect2, varscan2
- EZH2 | c.712G>T p.E238* | Nonsense Mutation (SNP) | VAF 46/262 reads (18%) | called by muse, mutect2, varscan2
- GNA15 | c.742G>A p.E248K | Missense Mutation (SNP) | VAF 42/255 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.228); called by muse, mutect2, varscan2
- KIF4B | c.829C>A p.L277I | Missense Mutation (SNP) | VAF 247/631 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MAGEB17 | c.94G>A p.A32T | Missense Mutation (SNP) | VAF 130/739 reads (18%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.767); called by muse, mutect2, varscan2
- MARK2 | c.2029G>A p.G677S (on ENST00000402010 / NM_001039469.2; = p.G613S on NM_004954.5) | Missense Mutation (SNP) | VAF 57/274 reads (21%) | SIFT tolerated (0.51); PolyPhen benign (0); called by muse, mutect2, varscan2
- MIOX | c.399_400insA p.E134Rfs*33 | Frame Shift Ins (INS) | VAF 67/435 reads (15%) | called by mutect2, pindel, varscan2
- MYOM2 | c.610A>G p.R204G | Missense Mutation (SNP) | VAF 145/502 reads (29%) | SIFT tolerated (0.33); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- PDE8A | c.244_249del p.V82_L83del | In Frame Del (DEL) | VAF 54/235 reads (23%) | called by mutect2, pindel, varscan2
- PTEN | c.299T>G p.L100R | Missense Mutation (SNP) | VAF 63/310 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SHANK1 | c.2137C>T p.R713* | Nonsense Mutation (SNP) | VAF 101/520 reads (19%) | called by muse, mutect2, varscan2
- SMARCA5 | c.1391A>T p.D464V | Missense Mutation (SNP) | VAF 58/232 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- SNTG1 | c.1528A>G p.T510A | Missense Mutation (SNP) | VAF 127/407 reads (31%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0); called by muse, mutect2, varscan2
- SOX4 | c.1242dup p.E415* | Frame Shift Ins (INS) | VAF 113/666 reads (17%) | called by mutect2, pindel, varscan2
- TSHZ3 | c.628G>A p.G210R | Missense Mutation (SNP) | VAF 67/505 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TSPYL2 | c.250del p.I84Sfs*63 | Frame Shift Del (DEL) | VAF 140/856 reads (16%) | called by pindel, varscan2
- WASHC1 | c.709G>C p.D237H | Missense Mutation (SNP) | VAF 38/150 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.17); called by muse, mutect2
- ANKFN1 | c.1545C>T p.L515= | Silent (SNP) | VAF 54/296 reads (18%) | catalogued as rs770244166; called by muse, mutect2, varscan2
- C11orf95 | c.600G>A p.E200= | Silent (SNP) | VAF 161/684 reads (24%) | called by mutect2, varscan2
- DOK3 | c.96G>A p.L32= | Silent (SNP) | VAF 244/586 reads (42%) | called by muse, mutect2, varscan2
- GGN | c.1218C>T p.P406= | Silent (SNP) | VAF 132/627 reads (21%) | called by muse, mutect2, varscan2
- GLRA3 | c.321G>A p.A107= | Silent (SNP) | VAF 72/282 reads (26%) | catalogued as rs201476578, COSV56866241; called by muse, mutect2, varscan2
- HBD | c.141G>A p.G47= | Silent (SNP) | VAF 71/417 reads (17%) | catalogued as COSV99496617; called by muse, mutect2, varscan2
- HRNR | c.2133T>C p.S711= | Silent (SNP) | VAF 99/519 reads (19%) | called by muse, mutect2, varscan2
- KCNA10 | c.1065G>A p.S355= | Silent (SNP) | VAF 106/449 reads (24%) | catalogued as rs566195238, COSV63904206; called by muse, mutect2, varscan2
- KIAA2012 | c.1317C>T p.H439= | Silent (SNP) | VAF 106/303 reads (35%) | catalogued as rs745369893, COSV99862421; called by muse, mutect2, varscan2
- KRT82 | c.675G>A p.L225= | Silent (SNP) | VAF 83/385 reads (22%) | catalogued as rs758654552, COSV99233356; called by muse, mutect2, varscan2
- LRIF1 | c.1485C>A p.V495= | Silent (SNP) | VAF 76/372 reads (20%) | called by muse, mutect2, varscan2
- MEGF6 | c.3426C>T p.H1142= | Silent (SNP) | VAF 158/676 reads (23%) | catalogued as rs375100441; called by muse, mutect2, varscan2
- MTMR1 | c.21G>A p.A7= | Silent (SNP) | VAF 28/234 reads (12%) | called by muse, varscan2
- PSMC4 | c.609C>T p.L203= | Silent (SNP) | VAF 91/456 reads (20%) | catalogued as rs1448827771; called by muse, mutect2, varscan2
- SLC1A5 | c.279C>A p.G93= | Silent (SNP) | VAF 150/728 reads (21%) | called by muse, mutect2, varscan2
- TMEM119 | c.204G>C p.G68= | Silent (SNP) | VAF 130/634 reads (21%) | called by muse, mutect2, varscan2
- TPRX1 | c.198G>A p.A66= | Silent (SNP) | VAF 134/536 reads (25%) | catalogued as rs537091280; called by muse, varscan2
- TTN | c.29268C>T p.I9756= (on ENST00000591111; = p.I8829= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 98/275 reads (36%) | catalogued as rs369709449, COSV59976609; called by muse, mutect2, varscan2
- USP13 | c.1275T>G p.S425= | Silent (SNP) | VAF 53/466 reads (11%) | called by muse, mutect2, varscan2
